Somatic mutation profile of tumor specimen MMRF_2394_1_BM_CD138pos (aliquot MMRF_2394_1_BM_CD138pos_T3_KHS5U_K14005) from MMRF case MMRF_2394, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.9 years (24,450 days).
Specimen MMRF_2394_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d92b401-c072-46ec-8d36-a15401063f7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2394_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2394_1_PB_Whole_C1_KHS5U_K14004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a224245-0e7e-46a2-a042-d56daa92b5da

The open-access MAF lists 86 somatic variants for this specimen: 37 protein-altering or splice-affecting, 9 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 23, Silent 9, Intron 7, 5'UTR 4, 3'Flank 3, RNA 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COQ8A | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs773489358, COSV64659199; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CXCL2 | c.261C>A p.N87K | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs752706721; called by muse, mutect2, varscan2
- DSC1 | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs774457500, COSV57143005; called by muse, mutect2, varscan2
- DUSP12 | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100909677; called by muse, mutect2, varscan2
- EYS | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 79/352 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs764308269, COSV60986589; called by muse, mutect2, varscan2
- MYO5B | c.2444C>T p.A815V | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs748227747, COSV53213052; called by muse, mutect2, varscan2
- PKHD1 | c.3839G>A p.R1280H | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374233100; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PMVK | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs149231731; called by muse, mutect2, varscan2
- PPEF2 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1488439021, COSV54420248, COSV54420279; called by muse, mutect2, varscan2
- ROBO1 | c.1396G>A p.V466I | Missense Mutation (SNP) | VAF 95/269 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as rs1366637977; called by muse, mutect2, varscan2
- SERINC3 | c.1187A>G p.N396S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs552691171; called by muse, mutect2, varscan2
- SLC27A6 | c.1481C>T p.T494I | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs144856578; called by muse, mutect2, varscan2
- USP7 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61213996; called by muse, mutect2, varscan2
- YOD1 | c.805G>C p.D269H | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as rs1196499438; called by muse, mutect2, varscan2
- ZIC4 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.201); catalogued as COSV67174506; called by muse, mutect2, varscan2
- AMER3 | c.749G>T p.C250F | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTLN | c.1489A>T p.I497F | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- CRISP2 | c.509G>T p.C170F | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- GRIN1 | c.2528C>T p.A843V | Missense Mutation (SNP) | VAF 87/236 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- IGHE | c.871T>A p.W291R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KREMEN2 | c.890T>C p.L297P | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- LOXL2 | c.858G>A p.M286I | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K19 | c.3497A>C p.Y1166S | Missense Mutation (SNP) | VAF 74/637 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MNAT1 | c.253A>G p.R85G | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2
- MYO5B | c.2699G>C p.R900T | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- NR2E3 | c.12A>C p.R4S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR8J1 | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PKP3 | c.671G>C p.S224T | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PLXNA2 | c.5677G>A p.E1893K | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PWWP3B | c.1430G>A p.R477K | Missense Mutation (SNP) | VAF 69/100 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RAPGEF5 | c.295+7C>G | Splice Region (SNP) | VAF 41/348 reads (12%) | called by muse, mutect2, varscan2
- SIX6 | c.228C>A p.N76K | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SPTBN1 | c.3662A>T p.N1221I | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- SRSF7 | c.278G>C p.R93T | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- STEAP2 | c.1432A>G p.T478A | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2
- TNFAIP6 | c.527G>A p.S176N | Missense Mutation (SNP) | VAF 95/279 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WASF2 | c.490A>C p.M164L | Missense Mutation (SNP) | VAF 76/204 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- ANKS4B | c.219C>G p.A73= | Silent (SNP) | VAF 59/190 reads (31%) | called by muse, mutect2, varscan2
- CCDC74B | c.1083C>T p.A361= | Silent (SNP) | VAF 4/99 reads (4%) | catalogued as rs1372732086; called by muse, mutect2
- IGHV3-30 | c.51C>A p.V17= | Silent (SNP) | VAF 33/396 reads (8%) | called by muse, mutect2
- IVL | c.978G>A p.L326= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs1481509257; called by muse, mutect2, varscan2
- MEGF10 | c.2973C>T p.N991= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs375982019; called by mutect2, varscan2
- MXRA5 | c.4938G>C p.P1646= | Silent (SNP) | VAF 63/94 reads (67%) | catalogued as COSV54232324; called by muse, mutect2, varscan2
- NLGN4Y | c.882C>T p.A294= | Silent (SNP) | VAF 38/57 reads (67%) | called by muse, mutect2, varscan2
- SELENOI | c.648C>T p.F216= | Silent (SNP) | VAF 40/137 reads (29%) | called by muse, mutect2, varscan2
- THEMIS | c.636G>A p.T212= | Silent (SNP) | VAF 45/49 reads (92%) | catalogued as rs752042343, COSV64069130; called by muse, mutect2, varscan2
- ABCC5 | c.*707G>A | 3'UTR (SNP) | VAF 48/114 reads (42%) | catalogued as COSV99657040; called by muse, mutect2, varscan2
- ACSM5 | c.*50T>A | 3'UTR (SNP) | VAF 127/414 reads (31%) | called by muse, mutect2, varscan2
- AGPAT3 | c.*2926C>T | 3'UTR (SNP) | VAF 59/170 reads (35%) | catalogued as rs777372035; called by muse, mutect2, varscan2
- AGPAT4 | c.*3091G>A | 3'UTR (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- ALKBH2 | c.-2+25A>G | Intron (SNP) | VAF 28/127 reads (22%) | called by muse, mutect2, varscan2
- ARL11 | c.*1135_*1137del | 3'UTR (DEL) | VAF 6/49 reads (12%) | catalogued as rs1402884382; called by pindel, varscan2
- BAGE2 | n.949C>T | RNA (SNP) | VAF 36/581 reads (6%) | called by muse, mutect2
- C2orf91 | n.2628G>T | RNA (SNP) | VAF 45/136 reads (33%) | called by muse, mutect2, varscan2
- CDC42SE2 | chr5:131398365 G>A | 3'Flank (SNP) | VAF 14/339 reads (4%) | called by muse, mutect2
- CDS1 | c.*2308T>C | 3'UTR (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- COMMD9 | c.*429A>T | 3'UTR (SNP) | VAF 24/82 reads (29%) | called by mutect2, varscan2
- CT83 | c.-80G>A | 5'UTR (SNP) | VAF 66/101 reads (65%) | called by muse, mutect2, varscan2
- DALRD3 | c.927+59T>C | Intron (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- DDB2 | c.128-96A>G | Intron (SNP) | VAF 43/106 reads (41%) | called by muse, mutect2, varscan2
- DDX10 | c.-5C>T | 5'UTR (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- FEM1AP2 | n.1048G>A | RNA (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- HECA | c.*1424T>C | 3'UTR (SNP) | VAF 11/14 reads (79%) | called by muse, mutect2, varscan2
- IL16 | chr15:81311936 G>C | 3'Flank (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- ITGA1 | c.*682A>C | 3'UTR (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- LMBRD2 | c.*1563A>T | 3'UTR (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- MALSU1 | c.*425C>T | 3'UTR (SNP) | VAF 29/54 reads (54%) | called by muse, mutect2, varscan2
- MLLT3 | c.*3538A>C | 3'UTR (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- NES | c.*196A>C | 3'UTR (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- NIPSNAP2 | c.*333del | 3'UTR (DEL) | VAF 18/48 reads (38%) | called by mutect2, varscan2
- OAS3 | c.3105-111G>A | Intron (SNP) | VAF 22/48 reads (46%) | called by muse, varscan2
- PDPK1 | c.*5402T>A | 3'UTR (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
- PIGG | c.*360C>A | 3'UTR (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- PLPP6 | c.-30C>T | 5'UTR (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- RMND5A | c.*867C>T | 3'UTR (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2
- RPRD2 | chr1:150473792 G>A | 3'Flank (SNP) | VAF 27/128 reads (21%) | catalogued as rs587731073; called by muse, mutect2, varscan2
- SEZ6L | c.*1319C>T | 3'UTR (SNP) | VAF 16/126 reads (13%) | catalogued as rs879389092; called by muse, mutect2, varscan2
- SGCZ | c.*254G>T | 3'UTR (SNP) | VAF 34/97 reads (35%) | called by muse, mutect2, varscan2
- SHISA9 | c.*212G>A | 3'UTR (SNP) | VAF 60/157 reads (38%) | called by muse, mutect2, varscan2
- SLC17A6 | c.-58G>A | 5'UTR (SNP) | VAF 56/458 reads (12%) | catalogued as COSV99581180; called by muse, mutect2, varscan2
- SVOP | c.*1455C>T | 3'UTR (SNP) | VAF 35/164 reads (21%) | called by muse, mutect2, varscan2
- TBX3 | c.717+109G>A | Intron (SNP) | VAF 6/26 reads (23%) | catalogued as rs1163813914; called by muse, mutect2, varscan2
- TPK1 | c.*611G>A | 3'UTR (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- TRMT2A | c.709-10C>T | Intron (SNP) | VAF 34/150 reads (23%) | catalogued as rs767404596; called by muse, mutect2, varscan2
- ZCCHC24 | c.*50G>T | 3'UTR (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2
- ZNF251 | c.277+220T>A | Intron (SNP) | VAF 28/195 reads (14%) | catalogued as rs1563773165; called by muse, mutect2, varscan2
